Somatic mutation profile of tumor specimen 0DITT4 from CCDI case PBBVRE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.7 years (6,095 days).
Specimen 0DITT4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a490f71d-5631-4665-9055-9499076109d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIFIM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac641612-302d-4a0e-93e6-a7a830244cf6

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1638C>A p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 188/476 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779707422, COSV58329537, COSV58330551; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.854T>C p.F285S | Missense Mutation (SNP) | VAF 127/354 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121918463, CM021134, CM060447, COSV61005134; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.3641T>A p.M1214K | Missense Mutation (SNP) | VAF 320/883 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- PCDH11Y | c.127G>A p.A43T (on ENST00000400457 / NM_032973.2; = p.A32T on NM_032971.3) | Missense Mutation (SNP) | VAF 60/620 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.115); called by muse, mutect2
- ZSWIM6 | c.2316T>C p.Y772= | Silent (SNP) | VAF 53/959 reads (6%) | called by muse, mutect2
- PRSS22 | c.83-30G>A | Intron (SNP) | VAF 90/288 reads (31%) | catalogued as rs374648893; called by muse, mutect2, varscan2
- SSPOP | n.11464G>A | RNA (SNP) | VAF 134/346 reads (39%) | catalogued as rs1473336934, COSV65131838; called by muse, mutect2, varscan2
